Somatic mutation profile of tumor specimen 0DJA06 from CCDI case PBBWNM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 8.9 years (3,268 days).
Specimen 0DJA06: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c72715f2-652f-4946-8bf9-3d9122e1db9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ9ZU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87e3b924-41f2-476e-89a0-5eab61c48ef5

The open-access MAF lists 102 somatic variants for this specimen: 72 protein-altering or splice-affecting, 15 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 15, Intron 7, Nonsense Mutation 5, 5'UTR 4, Frame Shift Del 3, 3'UTR 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 113/472 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMHR2 | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 58/597 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151253, COSV57687076; called by muse, mutect2
- ANKRD18A | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 96/664 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs561815251, COSV68803629; called by muse, mutect2, varscan2
- C1orf87 | c.1589C>G p.S530W | Missense Mutation (SNP) | VAF 115/535 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as COSV64596223; called by muse, mutect2, varscan2
- FBXW9 | c.844G>A p.D282N (on ENST00000587955; = p.D292N on NM_032301.3) | Missense Mutation (SNP) | VAF 69/420 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745933672; called by muse, mutect2, varscan2
- FRMD1 | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs376687499; called by muse, mutect2, varscan2
- GPAT4 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 89/620 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1343293234; called by muse, mutect2, varscan2
- ITFG1 | c.1810G>C p.A604P | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100278196; called by muse, mutect2, varscan2
- ITGA5 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 97/529 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs897973104, COSV53219701; called by muse, mutect2, varscan2
- LRRN1 | c.1534G>C p.A512P | Missense Mutation (SNP) | VAF 87/386 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV60014083; called by muse, mutect2, varscan2
- MST1R | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 25/313 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV56574502; called by muse, mutect2
- MXI1 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 136/723 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs992496003; called by muse, mutect2, varscan2
- MYO7A | c.2005C>G p.R669G | Missense Mutation (SNP) | VAF 111/602 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs111033201, CM981338; called by muse, mutect2, varscan2
- NCAPD3 | c.4105C>T p.R1369W | Missense Mutation (SNP) | VAF 153/667 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs752297905, COSV73187908; called by muse, mutect2, varscan2
- NUP54 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 227/544 reads (42%) | catalogued as rs763061508, COSV53577330, COSV99345169; called by muse, mutect2, varscan2
- NYAP2 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 60/472 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs376429827; called by muse, mutect2, varscan2
- OPHN1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375650816, COSV62785888; called by muse, mutect2, varscan2
- PCDHA10 | c.1820C>G p.S607W | Missense Mutation (SNP) | VAF 207/857 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56532328; called by muse, mutect2
- PITPNC1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 1303/1556 reads (84%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as rs1371207961, COSV55445476; called by muse, mutect2, varscan2
- RTN2 | c.1060A>T p.T354S | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.338); catalogued as COSV55594291; called by muse, mutect2, varscan2
- SETD1A | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 44/621 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52688259; called by muse, mutect2
- SIGLEC9 | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.105); catalogued as rs746646407; called by muse, mutect2, varscan2
- TCTN3 | c.988A>T p.T330S | Missense Mutation (SNP) | VAF 77/374 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.596); catalogued as COSV56448439; called by muse, mutect2, varscan2
- TMEM192 | c.116G>T p.R39I | Missense Mutation (SNP) | VAF 129/647 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60585491; called by muse, mutect2, varscan2
- TMTC2 | c.1616A>G p.E539G | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.188); catalogued as rs772739295; called by muse, mutect2, varscan2
- TPO | c.2072T>A p.L691Q | Missense Mutation (SNP) | VAF 131/845 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61096398; called by muse, mutect2, varscan2
- TRPM2 | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 86/672 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs749888700, COSV55973191; called by muse, mutect2, varscan2
- TTLL9 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 93/518 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs776756851; called by muse, mutect2, varscan2
- ACSM5 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 73/362 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- AGT | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 63/614 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPI | c.1500C>A p.C500* | Nonsense Mutation (SNP) | VAF 93/656 reads (14%) | called by muse, mutect2, varscan2
- ANKRD17 | c.4934C>G p.T1645S | Missense Mutation (SNP) | VAF 108/477 reads (23%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP26 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 72/516 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ATG9A | c.1349_1353del p.D450Vfs*4 | Frame Shift Del (DEL) | VAF 131/994 reads (13%) | called by mutect2, pindel, varscan2
- BSN | c.3826C>G p.R1276G | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- COL4A4 | c.2427A>C p.K809N | Missense Mutation (SNP) | VAF 119/665 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CRYZ | c.680A>C p.N227T | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- CTNNA1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 85/610 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CYFIP1 | c.2562C>G p.N854K | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- DIP2A | c.1296A>T p.L432F | Missense Mutation (SNP) | VAF 61/446 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DOCK4 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 211/350 reads (60%) | called by muse, mutect2, varscan2
- EFNA2 | c.12_22del p.Q5Afs*59 | Frame Shift Del (DEL) | VAF 48/260 reads (18%) | called by mutect2, varscan2
- EYS | c.6236C>A p.A2079D | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by mutect2, varscan2
- FBN2 | c.2978G>C p.R993P | Missense Mutation (SNP) | VAF 68/464 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FFAR2 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 68/414 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FGF14 | c.107A>T p.N36I | Missense Mutation (SNP) | VAF 83/619 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HIRA | c.617G>C p.W206S | Missense Mutation (SNP) | VAF 203/1031 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HK3 | c.1006T>A p.C336S | Missense Mutation (SNP) | VAF 115/784 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- JADE1 | c.1440_1443dup p.Q482Gfs*7 | Frame Shift Ins (INS) | VAF 113/474 reads (24%) | called by mutect2, pindel, varscan2
- JMJD1C | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 82/555 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- KCNA3 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- KIF21B | c.2703G>T p.K901N | Missense Mutation (SNP) | VAF 173/394 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- LGALS4 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LIG4 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 84/861 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2
- MTMR9 | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 86/497 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOS3 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 99/371 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NTSR1 | c.1000T>G p.W334G | Missense Mutation (SNP) | VAF 85/557 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52R1 | c.495G>C p.M165I | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OR9A2 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POSTN | c.542del p.N181Mfs*3 | Frame Shift Del (DEL) | VAF 104/953 reads (11%) | called by mutect2, pindel, varscan2
- POTEJ | c.2664G>T p.Q888H | Missense Mutation (SNP) | VAF 88/841 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRR5 | c.904G>A p.G302S (on ENST00000336985 / NM_181333.4; = p.G293S on NM_015366.4) | Missense Mutation (SNP) | VAF 88/1092 reads (8%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- RBPJL | c.1069T>A p.S357T | Missense Mutation (SNP) | VAF 67/1157 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- RHEX | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 112/600 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- SERPINB11 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 139/427 reads (33%) | called by muse, mutect2, varscan2
- SERPINI2 | c.446T>C p.M149T | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM114 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 138/328 reads (42%) | called by muse, mutect2, varscan2
- URI1 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP5 | c.1748T>C p.V583A | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- VSIG2 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- ZNF329 | c.1159A>T p.I387F | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZNF534 | c.812C>A p.A271E (on ENST00000332323 / NM_001143939.3; = p.A258E on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/550 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- ABCA12 | c.663T>C p.S221= | Silent (SNP) | VAF 85/590 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.1113T>C p.S371= (on ENST00000395184 / NM_001025616.3; = p.S278= on NM_031305.3) | Silent (SNP) | VAF 84/331 reads (25%) | called by muse, mutect2, varscan2
- C2orf15 | c.111G>A p.A37= | Silent (SNP) | VAF 112/746 reads (15%) | catalogued as rs778098003; called by muse, mutect2, varscan2
- DCC | c.195C>T p.S65= | Silent (SNP) | VAF 323/988 reads (33%) | catalogued as rs766772715, COSV59098207, COSV59111345; called by muse, mutect2, varscan2
- DPP10 | c.2158T>C p.L720= | Silent (SNP) | VAF 57/381 reads (15%) | called by muse, mutect2, varscan2
- GGT1 | c.1308C>G p.P436= | Silent (SNP) | VAF 175/930 reads (19%) | called by muse, mutect2, varscan2
- GPR39 | c.234G>A p.S78= | Silent (SNP) | VAF 63/514 reads (12%) | catalogued as rs1395656165, COSV100257598; called by muse, mutect2, varscan2
- LRRK1 | c.5019A>G p.T1673= | Silent (SNP) | VAF 142/247 reads (57%) | called by muse, mutect2, varscan2
- NCAM1 | c.969G>A p.E323= | Silent (SNP) | VAF 104/532 reads (20%) | called by muse, mutect2, varscan2
- OSBPL6 | c.93C>T p.D31= | Silent (SNP) | VAF 22/430 reads (5%) | called by muse, mutect2
- SECISBP2L | c.282C>T p.P94= | Silent (SNP) | VAF 211/318 reads (66%) | called by muse, mutect2, varscan2
- TACC2 | c.6234C>T p.I2078= (on ENST00000334433; = p.I156= on NM_006997.4) | Silent (SNP) | VAF 89/484 reads (18%) | called by muse, mutect2, varscan2
- TEX51 | c.477G>C p.R159= (on ENST00000643416; = p.R135= on NM_001322244.2) | Silent (SNP) | VAF 75/490 reads (15%) | called by mutect2, varscan2
- VN1R2 | c.1134C>T p.C378= | Silent (SNP) | VAF 20/582 reads (3%) | catalogued as COSV100447856; called by muse, mutect2
- WDR49 | c.870G>A p.A290= (on ENST00000308378 / NM_001366158.1; = p.A631= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 195/470 reads (41%) | catalogued as rs200046064, COSV57706589; called by muse, mutect2, varscan2
- APBA3 | c.617-42A>T | Intron (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- C7orf57 | c.*87del | 3'UTR (DEL) | VAF 22/76 reads (29%) | catalogued as rs1032408797; called by mutect2, varscan2
- C8orf33 | c.550+101del | Intron (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- DMKN | c.1239+277G>T | Intron (SNP) | VAF 81/441 reads (18%) | called by muse, mutect2, varscan2
- HTR4 | c.*73G>A | 3'UTR (SNP) | VAF 12/81 reads (15%) | catalogued as COSV58802470; called by muse, mutect2, varscan2
- NKAIN3 | c.472-54301G>T | Intron (SNP) | VAF 104/541 reads (19%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5436G>C | Intron (SNP) | VAF 33/162 reads (20%) | called by muse, mutect2, varscan2
- PHYHIPL | c.106+628A>T | Intron (SNP) | VAF 52/279 reads (19%) | called by muse, mutect2, varscan2
- POU3F3 | c.-34G>T | 5'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | chr22:44702386 C>T | 5'Flank (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- RAB6A | c.129+17A>C | Intron (SNP) | VAF 57/316 reads (18%) | called by muse, mutect2, varscan2
- SALL2 | c.-38G>C | 5'UTR (SNP) | VAF 5/111 reads (5%) | called by muse, mutect2
- TNRC18 | chr7:5428307 C>A | 5'Flank (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.-80G>A | 5'UTR (SNP) | VAF 50/141 reads (35%) | called by muse, mutect2, varscan2
- ZNF100 | c.-129C>G | 5'UTR (SNP) | VAF 50/420 reads (12%) | called by muse, mutect2, varscan2
